Somatic mutation profile of tumor specimen TCGA-XE-A9SE-01A (aliquot TCGA-XE-A9SE-01A-21D-A435-10) from TCGA case TCGA-XE-A9SE, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 35.2 years (12,850 days).
Specimen TCGA-XE-A9SE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d9dc21c-83fe-4201-bcf0-253037160fed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-A9SE-10A (Blood Derived Normal), aliquot TCGA-XE-A9SE-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e051de67-d3cb-44b4-824a-4a818e01416b

The open-access MAF lists 16 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Frame Shift Del 3, Frame Shift Ins 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GRIP1 | c.1612G>A p.E538K (on ENST00000359742 / NM_001379345.1; = p.E486K on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs369501964; called by muse, mutect2, varscan2
- LDLRAP1 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs142920998; called by muse, mutect2, varscan2
- PKD1L1 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs778975741; called by muse, mutect2, varscan2
- TET1 | c.1448C>G p.S483* | Nonsense Mutation (SNP) | VAF 7/84 reads (8%) | catalogued as COSV65381789; called by muse, mutect2
- TGFBRAP1 | c.2023A>G p.K675E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51510757; called by muse, mutect2, varscan2
- TUBA1A | c.518C>G p.P173R | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as CM124514; called by muse, mutect2, varscan2
- EVPL | c.5492_5493del p.Y1831* | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- MMP19 | c.1266_1288del p.T423Gfs*77 | Frame Shift Del (DEL) | VAF 14/172 reads (8%) | called by mutect2, pindel
- PLXNC1 | c.146T>A p.I49N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.464); called by muse, mutect2
- QRICH1 | c.1217A>T p.Y406F | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- SCARB2 | c.1023C>G p.H341Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TAS2R20 | c.379_380del p.S127Cfs*32 | Frame Shift Del (DEL) | VAF 26/204 reads (13%) | called by pindel, varscan2
- ZNF277 | c.135_139dup p.G47Vfs*8 | Frame Shift Ins (INS) | VAF 14/78 reads (18%) | called by mutect2, varscan2
- ZNF525 | c.1422G>T p.K474N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by muse, mutect2
- RABEPK | c.1050T>C p.C350= | Silent (SNP) | VAF 15/192 reads (8%) | called by muse, mutect2
